Somatic mutation profile of tumor specimen TCGA-UT-A88G-01B (aliquot TCGA-UT-A88G-01B-11D-A39R-32) from TCGA case TCGA-UT-A88G, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mesothelioma, biphasic, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 73.1 years (26,704 days).
Specimen TCGA-UT-A88G-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) af1eb984-d22f-4666-93ac-0b29ea73bc1e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UT-A88G-10A (Blood Derived Normal), aliquot TCGA-UT-A88G-10A-01D-A39U-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/594d5b64-75f2-4e04-b6e4-38918f7a31bb

The open-access MAF lists 33 somatic variants for this specimen: 24 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 18, Silent 9, Frame Shift Del 3, Splice Site 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDH9A1 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 54/98 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as rs377384593; called by muse, mutect2, varscan2
- BSN | c.9164G>A p.R3055H | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs866268771; called by muse, mutect2, varscan2
- DNAH10 | c.1567G>A p.E523K (on ENST00000409039; = p.E462K on NM_207437.3) | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.294); catalogued as rs757900300; called by muse, mutect2, varscan2
- GATA6 | c.531_548del p.A178_A183del | In Frame Del (DEL) | VAF 11/38 reads (29%) | catalogued as rs1198054146; called by mutect2, varscan2
- LRFN5 | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 64/88 reads (73%) | SIFT tolerated (0.15); PolyPhen benign (0.151); catalogued as rs553209511, COSV53242167, COSV53256587; called by muse, mutect2, varscan2
- MYO1D | c.790A>G p.I264V | Missense Mutation (SNP) | VAF 120/154 reads (78%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs1363296259; called by muse, mutect2, varscan2
- RAB11B | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs765316562; called by muse, mutect2, varscan2
- SRPK2 | c.481+1G>A p.X161_splice | Splice Site (SNP) | VAF 12/74 reads (16%) | catalogued as rs1402810107; called by muse, mutect2
- TAS1R2 | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs201197024, COSV64744384; called by muse, mutect2, varscan2
- TSPAN16 | c.554G>C p.S185T | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57443266; called by muse, mutect2, varscan2
- ASB14 | c.1513G>C p.V505L | Missense Mutation (SNP) | VAF 86/202 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ATF7 | c.1300T>A p.S434T (on ENST00000548446 / NM_001366555.2; = p.S423T on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- CAPN3 | c.2185-1G>A p.X729_splice | Splice Site (SNP) | VAF 77/178 reads (43%) | called by muse, mutect2, varscan2
- DTWD1 | c.101A>T p.D34V | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- FBXL12 | c.579del p.L194Wfs*42 | Frame Shift Del (DEL) | VAF 116/238 reads (49%) | called by mutect2, pindel, varscan2
- LACTB | c.408del p.E137Kfs*7 | Frame Shift Del (DEL) | VAF 62/192 reads (32%) | called by mutect2, pindel, varscan2
- LYN | c.555T>G p.I185M | Missense Mutation (SNP) | VAF 77/190 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYO16 | c.545A>C p.E182A | Missense Mutation (SNP) | VAF 35/47 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- NEU1 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 48/57 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- OGDHL | c.2003G>A p.G668D | Missense Mutation (SNP) | VAF 28/40 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PFKFB4 | c.209C>G p.T70S | Missense Mutation (SNP) | VAF 60/131 reads (46%) | PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- RWDD2B | c.277G>T p.V93L | Missense Mutation (SNP) | VAF 45/86 reads (52%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- SKIL | c.12_22del p.Q5Lfs*8 | Frame Shift Del (DEL) | VAF 35/132 reads (27%) | called by mutect2, pindel, varscan2
- TAS2R40 | c.445T>C p.S149P | Missense Mutation (SNP) | VAF 57/141 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AGTR2 | c.549C>T p.D183= | Silent (SNP) | VAF 51/120 reads (43%) | catalogued as rs782079778; called by muse, mutect2, varscan2
- ARID2 | c.4791T>G p.P1597= | Silent (SNP) | VAF 56/143 reads (39%) | called by muse, mutect2, varscan2
- CATSPERD | c.1644C>T p.Y548= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as rs758776815, COSV58467960; called by muse, mutect2, varscan2
- DGKZ | c.93C>G p.P31= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs781738735; called by muse, varscan2
- KIAA1522 | c.1779C>G p.T593= (on ENST00000373480 / NM_001198972.2; = p.T652= on NM_020888.3) | Silent (SNP) | VAF 30/66 reads (45%) | called by muse, mutect2, varscan2
- MEDAG | c.408T>C p.L136= | Silent (SNP) | VAF 93/116 reads (80%) | catalogued as rs928973001; called by muse, mutect2, varscan2
- RUNDC3B | c.927A>G p.Q309= | Silent (SNP) | VAF 46/103 reads (45%) | called by muse, mutect2, varscan2
- SMO | c.297G>A p.Q99= | Silent (SNP) | VAF 26/65 reads (40%) | called by muse, mutect2, varscan2
- TBL3 | c.2148C>T p.R716= | Silent (SNP) | VAF 67/83 reads (81%) | called by muse, mutect2, varscan2
